Somatic mutation profile of tumor specimen TARGET-50-PAJNTJ-01A (aliquot TARGET-50-PAJNTJ-01A-01D) from TARGET case TARGET-50-PAJNTJ, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.9 years (707 days).
Specimen TARGET-50-PAJNTJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5164097-295a-421e-9182-5af409b3032b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNTJ-10A (Blood Derived Normal), aliquot TARGET-50-PAJNTJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/407167a9-0f9f-452d-8eae-fafd81d4d75c

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS1B | c.2855C>T p.P952L (on ENST00000547776 / NM_152788.4; = p.P178L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59116522; called by muse, mutect2, varscan2
- ARHGAP40 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as rs543878310, COSV54809759; called by muse, mutect2, varscan2
- NCOA1 | c.2176C>G p.Q726E | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV56051248; called by muse, mutect2, varscan2
- OR2T8 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1292587547, COSV100178478, COSV60662050; called by muse, mutect2
- RUSC2 | c.3311G>A p.R1104H | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373601054; called by muse, mutect2, varscan2
- CREBBP | c.5446_5450dup p.V1818Afs*57 | Frame Shift Ins (INS) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- THAP11 | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
